Gene-level copy-number profile of tumor specimen HCM-CSHL-1269-C18-06A from HCMI case HCM-CSHL-1269-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen HCM-CSHL-1269-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cc934593-8079-476d-b402-a2f4b09a9a9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-1269-C18-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ee57a10c-ff85-493e-87d6-21faf37afdc2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 1,562; copy number 2: 19,170; copy number 3: 22,283; copy number 4: 12,625; copy number 5: 2,723; copy number 6: 11.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,894,677–7,896,716, 1 gene: DEFB4A.
- chr8:7,955,014–8,008,755, 3 genes (within-gene range 0–3): FAM66E, AC130365.1, USP17L8.
- chr8:7,990,415–8,226,614, 14 genes: DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1, AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.
- chr8:12,128,107–12,151,134, 4 genes (within-gene range 0–1): AC130366.1, USP17L7, USP17L2, DEFB109D.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–2): RNU6-457P.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,562. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
